Gene-level copy-number profile of tumor specimen TCGA-2G-AAHI-01A from TCGA case TCGA-2G-AAHI, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Seminoma, NOS; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 42.7 years (15,589 days).
Specimen TCGA-2G-AAHI-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file f894cfaa-1d43-4954-b3dd-adac87caca18.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator TCGA-2G-AAHI-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,733 have no estimate.
https://portal.gdc.cancer.gov/files/9ba3ab4f-f078-4dbc-aae0-7657e2e07c56

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 47; copy number 1: 1,278; copy number 2: 18,967; copy number 3: 26,806; copy number 4: 8,868; copy number 5: 1,614; copy number 6: 1,157; copy number 7: 47; copy number 8: 106.

Homozygous deletions (total copy number 0; autosomes only): 47 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:8,981,436–9,498,066, 43 genes: AC073648.3, AC073648.2, AC073648.5, AC073648.4, AC108519.1, SNRPCP16, AC073648.7, ENPP7P10, FAM86KP, ALG1L14P, FAM90A26, USP17L10, USP17L11, USP17L12, USP17L13, USP17L14P, USP17L15, USP17L16P, USP17L17, USP17L18, USP17L19, USP17L20, USP17L21, USP17L22, USP17L23, USP17L24, USP17L25, USP17L26, USP17L5, USP17L27, USP17L28, USP17L29, USP17L9P, USP17L30, USP17L6P, AC116655.1, DEFB108F, RNA5SP153, DEFB130D, DEFB131A, OR7E86P, OR7E85P, UNC93B7.
- chr11:55,602,360–55,666,195, 4 genes: OR4C11, OR4P4, OR4S2, OR4C6.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 153 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr11:109,741,625–109,823,893, 1 gene, copy number 7: LINC02715.
- chr11:109,907,004–110,171,841, 5 genes, copy number 7: TFAMP2, RPSAP50, AP001981.1, AP001889.1, ZC3H12C.
- chr22:15,282,557–18,894,407, 147 genes, copy number 7–8 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 766. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
